TARGET case TARGET-20-WSUAML — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/13ff019b-33b6-47d5-9ffc-e59d37bbc442

Biospecimens (1 sample)
- Sample TARGET-20-WSUAML-50A: Sample type: Cell Lines; Tissue type: Tumor; Specimen type: Derived Cell Line.
